Somatic mutation profile of cancer-model specimen HCM-CSHL-0403-C25-85D (3D Organoid, passage 12; aliquot HCM-CSHL-0403-C25-85D-01D-A85K-36), derived from the primary tumor of HCMI case HCM-CSHL-0403-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.9 years (23,352 days).
Specimen HCM-CSHL-0403-C25-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2899ef4-ca7f-4049-8da1-833ce0ed9aab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0403-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0403-C25-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4159651c-4806-4e19-b62e-6c8a0cc3f41e

The open-access MAF lists 59 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 11, 3'UTR 2, Nonsense Mutation 1, Intron 1, Frame Shift Del 1, 5'UTR 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 146/295 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.643A>C p.S215R | Missense Mutation (SNP) | VAF 138/138 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039484, CD1511147, COSV52675946, COSV52689203, COSV52876251, COSV53707934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY5 | c.3164G>A p.R1055H | Missense Mutation (SNP) | VAF 175/394 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs762578500, COSV59201616; called by muse, mutect2, varscan2
- CDKN2A | c.278C>G p.T93R | Missense Mutation (SNP) | VAF 320/321 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876659723, COSV58684508, COSV58684689, COSV58721866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COQ5 | c.576A>G p.G192= | Splice Region (SNP) | VAF 24/230 reads (10%) | catalogued as rs149646698; called by muse, mutect2, varscan2
- CUBN | c.8573G>A p.G2858E | Missense Mutation (SNP) | VAF 130/260 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.14); catalogued as COSV64727118; called by muse, mutect2, varscan2
- ELMO1 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 131/270 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1329010889; called by muse, mutect2, varscan2
- HAP1 | c.1457C>T p.T486M (on ENST00000310778 / NM_001367460.1; = p.T434M on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/314 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs782546957, COSV57880158; called by muse, mutect2
- KIAA1549L | c.3307C>T p.R1103W (on ENST00000321505; = p.R1400W on NM_012194.3) | Missense Mutation (SNP) | VAF 89/294 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747515119, COSV55769669; called by muse, mutect2, varscan2
- MC3R | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 247/531 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54764971; called by muse, mutect2, varscan2
- MS4A3 | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV53935228; called by muse, mutect2
- MYO15A | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 231/233 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1248557646, COSV52760772, COSV52769060; called by muse, mutect2, varscan2
- NALCN | c.3658G>A p.V1220I | Missense Mutation (SNP) | VAF 153/428 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.699); catalogued as rs771258062; called by muse, mutect2, varscan2
- NBEA | c.6391G>C p.E2131Q | Missense Mutation (SNP) | VAF 36/688 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as COSV59778864; called by muse, mutect2
- NETO1 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 75/130 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100199002; called by muse, mutect2, varscan2
- OR56A1 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 161/343 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs763572368, COSV57362486; called by muse, mutect2
- PEX14 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 108/257 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs770183471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLAA | c.234C>A p.D78E | Missense Mutation (SNP) | VAF 120/201 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV68305519; called by muse, mutect2, varscan2
- PRKAA2 | c.1396C>A p.L466I | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV64805940; called by muse, mutect2, varscan2
- PXDNL | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 160/346 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs766991284, COSV62488808; called by muse, mutect2, varscan2
- SEZ6L | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 11/332 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs1286924679; called by muse, mutect2
- SGCD | c.382C>A p.P128T (on ENST00000435422 / NM_001128209.2; = p.P129T on NM_000337.5) | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV61910844; called by muse, mutect2
- SLC12A3 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 145/311 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187885782, CM088242; called by muse, mutect2, varscan2
- ST8SIA1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 167/367 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV99683663; called by muse, mutect2, varscan2
- TENM2 | c.6625G>A p.G2209R (on ENST00000518659 / NM_001122679.2; = p.G1970R on NM_001080428.3) | Missense Mutation (SNP) | VAF 239/469 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756812300, COSV69133581; called by muse, mutect2, varscan2
- TLE4 | c.1551C>A p.H517Q | Missense Mutation (SNP) | VAF 150/298 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1337584176; called by muse, mutect2, varscan2
- TLR3 | c.1402T>C p.Y468H | Missense Mutation (SNP) | VAF 113/383 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.286); catalogued as rs1011578363; called by muse, mutect2, varscan2
- TMCO4 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 126/241 reads (52%) | catalogued as rs369962324; called by muse, mutect2, varscan2
- TSPAN10 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 304/578 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs771337272, COSV100148454; called by muse, mutect2, varscan2
- UNC5B | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 156/347 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs200337007; called by muse, mutect2, varscan2
- WEE1 | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 197/434 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV55197695; called by muse, mutect2, varscan2
- ZNF843 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 225/488 reads (46%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.111); catalogued as rs902170193, COSV59848266; called by muse, mutect2, varscan2
- COL1A2 | c.3533A>T p.Y1178F | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EFCAB8 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 121/277 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- GPRIN3 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 198/410 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.045); called by mutect2, varscan2
- IGHV1-69 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- LAG3 | c.1078T>C p.S360P | Missense Mutation (SNP) | VAF 130/241 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC9 | c.2590C>T p.P864S | Missense Mutation (SNP) | VAF 130/296 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NBEA | c.7296G>T p.K2432N | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- OR52E1 | c.817T>G p.F273V | Missense Mutation (SNP) | VAF 156/378 reads (41%) | called by muse, mutect2
- RALGAPA2 | c.1620dup p.A541Cfs*3 | Frame Shift Ins (INS) | VAF 178/413 reads (43%) | called by mutect2, pindel, varscan2
- TBL2 | c.222A>C p.Q74H | Missense Mutation (SNP) | VAF 196/374 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TGFBR2 | c.325_332del p.H109Yfs*20 | Frame Shift Del (DEL) | VAF 152/155 reads (98%) | called by mutect2, pindel, varscan2
- ZNF233 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 21/367 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2
- ACOT2 | c.504G>A p.L168= | Silent (SNP) | VAF 26/528 reads (5%) | called by muse, mutect2
- AMPD3 | c.729G>A p.P243= (on ENST00000396553 / NM_001025389.2; = p.P252= on NM_000480.3) | Silent (SNP) | VAF 168/379 reads (44%) | catalogued as rs780910038; called by muse, mutect2, varscan2
- BARHL2 | c.189T>G p.S63= | Silent (SNP) | VAF 212/485 reads (44%) | catalogued as COSV64980924; called by muse, mutect2, varscan2
- C5orf38 | c.99G>A p.P33= | Silent (SNP) | VAF 272/580 reads (47%) | catalogued as COSV57412608; called by muse, mutect2, varscan2
- CDH22 | c.1239C>T p.V413= | Silent (SNP) | VAF 259/500 reads (52%) | catalogued as COSV100953004, COSV64836522; called by muse, mutect2, varscan2
- DMRTC2 | c.655C>T p.L219= | Silent (SNP) | VAF 129/280 reads (46%) | called by muse, varscan2
- HADH | c.312G>T p.T104= | Silent (SNP) | VAF 22/395 reads (6%) | called by muse, mutect2
- IGSF9 | c.3183C>T p.G1061= (on ENST00000368094 / NM_001135050.2; = p.G1045= on NM_020789.4) | Silent (SNP) | VAF 83/506 reads (16%) | called by muse, mutect2, varscan2
- OR4M1 | c.48C>A p.G16= | Silent (SNP) | VAF 124/592 reads (21%) | catalogued as COSV100271481, COSV60061745; called by mutect2, varscan2
- PLCL1 | c.195C>T p.L65= | Silent (SNP) | VAF 33/463 reads (7%) | called by muse, mutect2
- TRRAP | c.3381C>A p.G1127= | Silent (SNP) | VAF 63/212 reads (30%) | called by muse, mutect2, varscan2
- CLP1 | c.-1G>T | 5'UTR (SNP) | VAF 18/526 reads (3%) | called by muse, mutect2
- NEB | c.11601+6151C>T | Intron (SNP) | VAF 169/662 reads (26%) | catalogued as rs775872152; called by muse, varscan2
- RCAN2 | c.*1251C>G | 3'UTR (SNP) | VAF 17/245 reads (7%) | called by muse, mutect2
- ULBP3 | c.*1G>A | 3'UTR (SNP) | VAF 71/71 reads (100%) | called by muse, mutect2, varscan2
